Somatic mutation profile of tumor specimen TCGA-BJ-A0ZJ-01A (aliquot TCGA-BJ-A0ZJ-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZJ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.0 years (13,149 days).
Specimen TCGA-BJ-A0ZJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 616608bd-f08d-4078-a6f4-10fea9a994e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZJ-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZJ-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dfa1eb7-c57e-457a-9231-a5b35718fe16

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRIM75P | c.1113dup p.T372Hfs*17 | Frame Shift Ins (INS) | VAF 61/259 reads (24%) | called by mutect2, pindel, varscan2
- CNEP1R1 | c.25+330G>A | Intron (SNP) | VAF 15/76 reads (20%) | catalogued as COSV66697168; called by muse, mutect2, varscan2
